Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0M4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0M4-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PERIAORTIC, BIOPSY -
TWO LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/2).

PART 2: LYMPH NODES, RIGHT COMMON ILIAC, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC TUMOR (0/1).

PART 3: LYMPH NODES, LEFT COMMON ILIAC, BIOPSY -
A. BENIGN FIBROADIPOSE TISSUE.
B. NO LYMPHOID TISSUE IS SEEN.

PART 4: LYMPH NODES, LEFT PERIAORTIC, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC TUMOR (0/1).

PART 5: LYMPH NODES, LEFT EXTERNAL ILIAC, BIOPSY -
FIVE LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/5).

PART 6: LYMPH NODES, LEFT OBTURATOR, BIOPSY -
FOUR LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/4).

PART 7: LYMPH NODES, RIGHT EXTERNAL ILIAC, BIOPSY -
FOUR LYMPH NODES, NEGATIVE FOR METASTATIC TUMOR (0/4).

PART 8: LYMPH NODES, RIGHT OBTURATOR, BIOPSY -
A. BENIGN FIBROADIPOSE TISSUE.
B. NO LYMPHOID TISSUE IS SEEN.

PART 9: UTERUS, CERVIX, BILATERAL OVARIES AND FALLOPIAN TUBES, VAGINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. ENDOMETRIAL ADENOCARCINOMA, MIXED ENDOMETRIOID AND CLEAR CELL TYPE, FIGO GRADE 3, NUCLEAR GRADE 3.
- B. TUMOR SIZE IS 3.6 CM.
- C. TUMOR INVADERS LESS THAN 5 % OF THE MYOMETRIAL THICKNESS.
- D. TUMOR INVOLVES 60% OF THE ENDOMETRIAL SURFACE (100% OF THE ANTERIOR SURFACE AND 20% OF THE POSTERIOR SURFACE).
- E. TUMOR INVOLVES LOWER UTERINE SEGMENT.
- F. NO ENDOCERVICAL INVOLVEMENT IS SEEN.
- G. NO LYMPHOVASCULAR SPACE INVASION IS SEEN.
- H. ADENOMYOSIS.
- I. LEIOMYOMA, 1.0 CM.
- J. RIGHT OVARY WITH PHYSIOLOGIC CHANGES.
- K. RIGHT FALLOPIAN TUBE WITH NO SIGNIFICANT PATHOLOGIC CHANGES.
- L. LEFT OVARY WITH PHYSIOLOGIC CHANGES.
- M. LEFT FALLOPIAN TUBE WITH DETACHED TUMOR WITHIN THE LUMEN.

COMMENT:

The companion pelvic wash cytology specimen [REDACTED] is negative for malignant cells.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE:

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

ARCHITECTURAL GRADE:

NUCLEAR GRADE:

TUMOR SIZE:

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

DEPTH OF INVASION**:

ANGIOLYMPHATIC INVASION:

OTHER:

LYMPH NODES POSITIVE:

LYMPH NODES EXAMINED:

T STAGE, PATHOLOGIC:

N STAGE, PATHOLOGIC:

M STAGE, PATHOLOGIC:

FIGO STAGE:

Endometroid adenocarcinoma, NOS, Clear cell carcinoma - 9% pw TSS
-email 1/10/10

Poorly differentiated (FIGO 3)

Poorly differentiated

Grade 3

Maximum dimension: 3.6 cm

Anterior endomyometrium: 100 %, Posterior endomyometrium: 20 %

Less than 1/2 thickness of myometrium

No

(epithelial, smooth muscle, others), Adenomyosis, Leiomyoma

Number of lymph nodes positive:: 0

Total number of lymph nodes examined: 17

pT1b

pN0

pMX

IB

ICD-0-3

adenocarcinoma, endometrioid
(w/ clear cell - 9%) 8380/3

Site: endometrium c54.1

hw 5/3/11

Source: NCI Genomic Data Commons file 05b4527e-0eec-4962-8054-cc098f4c56f3 (TCGA-BG-A0M4.95002D96-C9D8-43BE-ADD1-072E93994194.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).